Surgical pathology report (de-identified scan), TCGA case TCGA-DS-A0VN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-DS-A0VN-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3

Squamous cell carcinoma, NOS Page 1 of

Site: cervix, NOS 8070/3
C53.9

12/7/10
JW

Ordering MD:

Copies To:

DIAGNOSIS:

9. UTERUS, HYSTERECTOMY:

- Cervical invasive squamous cell carcinoma, moderately differentiated, keratinizing; see Comment
- Size: 8.0 cm
- Depth of invasion: 1.3 cm
- 0.1 cm from closest deep cervical margin
- 1.0 cm from closest vaginal cuff resection margin
- Extends to lower uterine segment/isthmus
- No tumor identified in parametrium
- No tumor identified in 8 small parametrial lymph nodes
- Lympho-vascular invasion is not identified
- Leiomyoma
- Adenomyosis and adenomyoma
- Benign secretory endometrium

1. RIGHT ADNEXA, SALPINGO-OOPHORECTOMY:

- Ovary with hemorrhagic corpus luteum cyst and cystic follicles
- Fallopian tube with cystic walthard rests
- No malignancy is identified

2. LEFT ADNEXA, SALPINGO-OOPHORECTOMY:

- Ovary with cystic follicles and focal organizing hemorrhage
- Fallopian tube with cystic walthard rest
- No malignancy is identified

3. LEFT PELVIC LYMPH NODE, BIOPSY:

- Three lymph nodes negative for malignancy

4. LEFT OBTURATOR, BIOPSY:

- Three lymph nodes negative for malignancy

5. RIGHT PELVIC LYMPH NODES, BIOPSY:

- One lymph node negative for malignancy

6. OBTURATOR, BIOPSY:

- One lymph node negative for malignancy

(continued on next page)□

Department of Pathology & Laboratory Medicine

Page: 2

7. RIGHT PARAMETRIUM, BIOPSY:

- Three small lymph nodes negative for malignancy

8. FROZEN SECTION OBTURATOR, BIOPSY:

- Two lymph nodes negative for malignancy

10. PERIAORTIC LYMPH NODE, BIOPSY:

- Four lymph nodes negative for malignancy

11. RIGHT COMMON ILIAC, BIOPSY:

- Two lymph nodes negative for malignancy

[page 2 of 4]
12. LEFT COMMON ILIAC, BIOPSY:
-Adipose tissue negative for malignancy

Comment: The tumor abuts the ectocervical-vaginal junction. Cervical intraepithelial neoplasia is not identified; however, essentially the entire cervix has been replaced by squamous cell carcinoma.

=====

HISTORY: Cervical carcinoma

MICROSCOPIC:

See Diagnosis.

GROSS:

1: RIGHT ADNEXA

Labeled "right adnexa" and received in formalin is an ovary with attached fallopian tube. The specimen weighs 13 grams. The ovary measures 3.7 x 2.2 x 1.5 cm and has firm yellow focally hemorrhagic mildly lobulated surface. Sectioning of the ovary reveals a corpus luteum measuring up to 2.2 cm in greatest dimension and also one smooth wall cyst filled with clear fluid and with a wall thickness up to 0.1 cm. The fallopian tube has fimbria at one end and is 3.7 cm long and has an average diameter of 0.7 cm. Attached to the fallopian tubes there are three thin wall translucent fluid filled cysts measuring from 0.1 to 0.2 cm in diameter. Sectioning of the tube reveal a patent lumen measuring up to 0.1 cm in diameter. Representative sections submitted.

A. Right ovary - 1

B. Right fallopian tube and mesosalpinx - 4

2: LEFT ADNEXA

Labeled "left adnexa" and received in formalin is an ovary with attached fallopian tube. The specimen weighs 9.0 grams. The ovary measures 3.0 x 1.7 x 1.2 cm, has pink-yellow lobulated smooth surface. Section reveals approximately eight cystic spaces ranging in size from 0.3 to 0.8 cm: The walls are smooth and have maximum thickness of 0.1 cm. The attached fallopian tube measures 4.0 cm in length and has a fimbriated end. The tube measures 0.5 cm in average diameter with tan-pink serosa. Section of the fallopian tube shows a lumen measuring up to 0.1 cm in diameter. Representative sections.

C. Left ovary - 1

D. Left fallopian tube and mesosalpinx - 3

(continued on next page)□

Department of Pathology & Laboratory Medicine

Page: 3

3: ~~LEFT PELVIC LYMPH NODE~~

Labeled "left pelvic lymph node" and received in formalin is an aggregate of soft yellow lobulated fat measuring 5.5 x 5.0 x 1.5 cm. Section of the fat reveals three soft tan unremarkable lymph nodes ranging in size from 0.8 to 1.4 cm. Lymph nodes are entirely submitted.

E. Two lymph nodes bisected - 4

F. One lymph node bisected - 2

4: LEFT OBTURATOR

Labeled "left obturator" and received in formalin is an aggregate of soft yellow lobulated fatty tissue measuring 5.0 x 5.0 x 0.8 cm. Section reveals three tan-pink soft unremarkable lymph nodes measuring from 1.0 cm to 2.7 cm. Lymph nodes are entirely submitted.

G. One lymph node bisected - 2

H, I. Lymph node bisected - 1 each

J. One lymph node bisected - 2

5: RIGHT PELVIC LYMPH NODES

Labeled "right pelvic lymph nodes" and received in formalin is an aggregate of soft yellow lobulated adipose tissue measuring 6.0 x 5.0 x 1.5 cm. Section reveals one soft tan-pink grossly unremarkable

[page 3 of 4]
lymph node measuring up to 2.0 cm in greatest dimension. Lymph node entirely submitted.

K. One lymph node bisected - 2

6: OBTURATOR

Labeled "obturator" and received in formalin is an aggregate of soft yellow lobulated fatty tissue measuring 4.0 x 3.5 x 0.8 cm. Sectioning reveals one soft tan-pink grossly unremarkable lymph node measuring 1.5 cm in greatest dimension. Lymph node entirely submitted.

L. One lymph node bisected - 2

7: RIGHT PARAMETRIUM

Labeled "right parametrium" and received in formalin is an irregular portion of tan-yellow focally hemorrhagic membranous adipose tissue measuring 2.5 x 2.0 x 0.3 cm. Entirely submitted.

M. 1

8: FROZEN SECTION OBTURATOR

Labeled "frozen section obturator", received fresh in the Operating Room for frozen section diagnosis and subsequently fixed in formalin are two lymph nodes measuring 3.5 x 1.5 x 0.8 cm and 4.5 x 1.8 x 1.5 cm. Two cuts of the larger lymph node was utilized for frozen section. The rest of the lymph node tissue entirely submitted.

N. Frozen section remnant - 2

O-Q. Large lymph node - multiple

R,S. Smaller lymph node - 4 each

9: UTERUS

Labeled "uterus" and received in formalin is a 260 gram hysterectomy specimen. The uterus is symmetric and measures 10.5 cm from fundus to ectocervix, 8.0 cm cornu to cornu and 6.5 cm anterior to posterior. The cervix is 4.0 cm long and has a maximum diameter of 8.5 cm. The cervix is largely replaced by a firm tan-red, ulcerated, fungating mass. The barrel shaped mass measures 8.0 x 5.0 x 3.0 cm. The mass is 0.1 cm, 0.6 cm, 0.4cm, and 0.6 cm from the

(continued on next page)□

Department of Pathology & Laboratory Medicine

Page: 4

deep cervical margins on the posterior, anterior, left, and right respectively (deep margin being the external surface of the cervix). A vaginal cuff surrounds the mass and measures 1.0 cm wide posteriorly to 4.0 cm wide anteriorly. The tumor is therefore 1 cm from the closest vaginal resection margin. The mass involves the whole endocervical canal and extends into the lower uterine segment/isthmus. The bulk of the uterine corpus is grossly uninvolved. The endometrial cavity measures 4.0 cm long and 3.7 cm wide, and is covered by tan soft, smooth endometrium that measures up to 0.5 cm in thickness. Section of the uterine corpus reveal mildly trabecular myometrium and two intramural and one subserosal, well circumscribed firm tan-white whorled masses without grossly evident hemorrhages or areas of necrosis. All resection margins are inked blue.

Representative section submitted.

T. Mass and posterior resection margin - 1

U. Left resection margin - 1

V. Posterior right vaginal resection margin - 2

W. Posterior left vaginal resection margin - 2

X. Anterior right vaginal resection margin - 2

Y. Anterior left vaginal resection margin - 2

Z. Mass and anterior resection margin - 1

AA. Myometrial tissue - 1

BB. Anterior uterine corpus - 1

CC. Posterior uterine corpus - 2

GG. Anterior lower uterine segment - 1

HH. Posterior lower uterine segment - 1

II. Mass and ectocervix-vaginal cuff junction- 1

[page 4 of 4]
10: PERIAORTIC LYMPH NODE

Labeled "periaortic lymph node" and received in formalin is an aggregate of soft yellow lobulated focal hemorrhagic adipose tissue measuring 2.2 x 2.0 x 0.5 cm. Sectioning reveals four soft tan-pink grossly unremarkable lymph nodes ranging in size from 0.6 to 1.4 cm. Lymph nodes entirely submitted.
DD. Four lymph nodes, two bisected - 6

11: RIGHT COMMON ILIAC

Labeled "right common iliac" and received in formalin are two soft tan-pink grossly unremarkable lymph nodes measuring 1.0 and 1.7 cm in greatest dimension. Entirely submitted.
EE. Two lymph nodes bisected - 4

12. LEFT COMMON ILIAC

Labeled "left common iliac" and received in formalin is an irregular portion of soft yellow lobulated fatty tissue measuring 1.5 x 0.6 x 0.2 cm. No lymph nodes identified.
Entirely submitted.
FF. 1

Gross dictated by
(

OPERATIVE CONSULT (FROZEN):

(continued on next page)□

Department of Pathology & Laboratory Medicine

Page: 5

FS #8: OBTURATOR LYMPH NODES:

Sampled representative sections (of the largest node): Reactive lymph node with no evidence of tumor
(M.D.)

Note: A 2.5 x 1.5 x 0.6 cm portion of tumor is harvested for Dr.

Special Studies: Frozen Section

See Also: None

DATE:

Pathologist

I, _____ M.D., the pathologist of record, have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

Date Finalled: (

Source: NCI Genomic Data Commons file 1861cde9-0cab-4501-b40a-e65db6f1dbaa (TCGA-DS-A0VN.F98AC018-6C95-44F5-BEF4-4A5C422970C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).